Somatic mutation profile of tumor specimen 0DUIXL from CCDI case PBCLFI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.4 years (2,339 days).
Specimen 0DUIXL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 595b6ab8-b2cc-4c1d-adc6-ea05697ee318.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUIWP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af1d1636-3ec9-45d3-8923-ce3158ff30f9

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TINAGL1 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as rs566858151, COSV54700029; called by muse, mutect2, varscan2
- RAPGEF4 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SLC2A6 | c.1254G>A p.W418* | Nonsense Mutation (SNP) | VAF 11/185 reads (6%) | called by muse, mutect2
- CHD8 | c.6654T>C p.S2218= (on ENST00000646647 / NM_001170629.2; = p.S1939= on NM_020920.4) | Silent (SNP) | VAF 40/339 reads (12%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 23/586 reads (4%) | called by muse, mutect2
